Surgical pathology report (de-identified scan), TCGA case TCGA-A2-A0CK, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Walter Reed, specimen TCGA-A2-A0CK-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient:
FMP/SSN:
DOB/Age/Sex
Location:
Physician(s):

(Age:) F Race: WHITE

Specimen #:

Taken:
Received:
Reported:

****AMENDED / ADDENDUM**** ICD-0-3

*Carcinoma, infiltrating lobules, NOS
8520/3
Site: breast, NOS C50.9
1/24/11*

SPECIMEN: RIGHT BREAST TISSUE

FINAL DIAGNOSIS:

BREAST, RIGHT INFERIOR LATERAL RETRO-AREOLA, EXCISION:
INFILTRATING LOBULAR CARCINOMA.
SURGICAL MARGINS POSITIVE FOR TUMOR.
TUMOR SIZE: 0.5 CM BY MICROSCOPY.
LOBULAR CARCINOMA IN SITU.
PERINEURAL INVOLVEMENT BY CARCINOMA.
MICROCALCIFICATIONS IDENTIFIED.
AJCC STAGING: STAGE I (T1, NX, MX), SEE COMMENT.

COMMENT:

(visiting pathology resident from . discussed the
above diagnosis with Dr. on at .

AMENDMENT

At the request of the clinician, tumor was evaluated for HER2-neu overexpression by immunohistochemical methods (DAKO HercepTest) with the following results:

HER2/neu overexpression: NEGATIVE (1+).

COMMENT: Membranous staining is interpreted on a scale of 0 to 3+ with positivity defined as 2+ or greater. Test performed at

Interpretation rendered by

**** Report Electronically Signed Out ****

[page 2 of 2]
-5

SURGICAL PATHOLOGY REPORT

Patient:

Specimen #:

ADDENDUM:

HER2/NEU BY FISH = 1.1 NOT AMPLIFIED

TEST: FISH for detection of HER2-neu gene amplification (Path Vision Her2 DNA probe by Vysis). Ratio of Her2-neu over chromosome 17 signals.

RANGE FOR INTERPRETATION:

Ratio less than 2.0: HER2-neu gene amplification not observed.

Ratio equal to or greater than 2.0: HER2-neu gene amplification observed.

ER/PR IMMUNOSTAINS ARE NEGATIVE.

CLINICAL DIAGNOSIS AND HISTORY:

40 FEMALE WITH SMALL 1X.6CM COMPLEX MASS BY U/S AT INFERIOR/LATERAL RETROAREOLAR

PRE-OPERATIVE DIAGNOSIS:

FIBROUS TISSUE VS MALIGNANCY

POST-OPERATIVE DIAGNOSIS:

Post-operative Diagnosis: SAA

GROSS DESCRIPTION:

RIGHT BREAST TISSUE "inferior lateral retro-areola" consists of a single irregularly shaped fragment of fibro fatty tissue, which previously has been inked and sectioned. When reapproximated, the specimen measures 2 x 1 x 1 cm. The previous sectioning reveals that the specimen is mostly fat with admixed fibrous tissue. The specimen is placed in its entirety in the 5 gray cassettes marked A1-A5. The specimen was previously inked blue before being received by this observer.

Source: NCI Genomic Data Commons file a5d19f9c-38b2-4454-ba7d-fd2a318d0a02 (TCGA-A2-A0CK.B065FC65-CD33-4878-AE2C-7E8C04F5ECAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).